Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4159, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4159-01A (Primary Tumor).

[page 1 of 2]
Other Related Data:

Billing Type: [REDACTED]
Financial Number: [REDACTED]

Clinical Diagnosis & History:

[REDACTED] with right renal mass.

Specimens Submitted:

- 1: SP: Rt. kidney [REDACTED]
2: SP: Paracaval lymph node [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, RIGHT, NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE II/IV. THE PATTERN OF GROWTH IS ACINAR. THE TUMOR GREATEST DIAMETER IS 7.0 CM. THE TUMOR IS CONFINED TO WITHIN GEROTA'S FASCIA. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. ONE BENIGN REGIONAL LYMPH NODE IS ALSO IDENTIFIED.
- 2) LYMPH NODES, PARACAVAL, EXCISION:
- MULTIPLE BENIGN LYMPH NODES.

*** [REDACTED]

Gross Description:

1) The specimen is received fresh, labeled "Right Kidney". It consists of an 840 gram kidney with perinephric fat. The surgical margins (ureter, artery and vein) appear uninvolved by pathologic process on a gross basis. Sectioning reveals a 13 x 5.5 x 5.5 cm kidney. In the superior pole of the kidney appears a circumscribed nodule. Further sectioning demonstrates that this nodule shows hemorrhagic and necrotic degeneration with golden-colored viable tumor. This nodule measures 6 x 4.5 x 5 cm. The tumor approaches, but does not appear to breach the Gerota's fascia of the superior pole of the kidney. The tumor does not appear to involve the perinephric fat. The tumor appears 1.5 cm from the hilum of the kidney. At the inferior portion of the tumor nodule

[page 2 of 2]
there appear tumor satellites that are still contiguous with the main tumor. This tumor satellite appears as much as 2 cm below the main tumor. This gives the maximum dimension of the tumor measurement at 7 cm. Representative portions of tumor and normal kidney parenchyma are given to TPS. Representative portions of the tumor and normal parenchyma of the kidney are submitted along with a perinephritic fat margin and the hilar margins. No adrenal gland is identified with this specimen.

Summary of Sections:

HM - hilar margins (ureter, vein and artery)
PM - perinephric fat margin
N - normal renal parenchyma
T - tumor

2) The specimen is received in formalin, labeled "Para-Caval Lymph Node". It consists of multiple fragments of fibroadipose tissue measuring 2.8 x 2.0 x 0.5 cm. Multiple lymph nodes are identified. The largest lymph node is bisected. Submitted entirely in three cassettes.

Summary of Sections:

BLN - bisected lymph node
LN - lymph node

Histo Stain Results/Comments:

Stain/Procedure Name	Result	Comment
----------------------	--------	---------

RECUT ADDITIONAL H&E

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	HM		1	M	N
	N		1	1	
	PM		1	1	
	T		7	7	
2	bln		2	2	N
	ln		1	1	

Source: NCI Genomic Data Commons file 7c642514-0013-4ba8-aef1-00c2f64454e7 (TCGA-BP-4159.2ADC9F54-12F4-482C-813B-46B82A5178FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).